Somatic mutation profile of tumor specimen C3L-03264-01 (aliquot CPT0225010006) from CPTAC case C3L-03264, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.5 years (26,833 days).
Specimen C3L-03264-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e7588b-ff71-4ec1-b858-cae3ad2fce2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03264-31 (Blood Derived Normal), aliquot CPT0226020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ee3eff3-6c2b-48a0-accd-0a0b4a7ee8eb

The open-access MAF lists 1,015 somatic variants for this specimen: 692 protein-altering or splice-affecting, 197 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 481, Silent 197, Frame Shift Del 114, Intron 66, Frame Shift Ins 36, Nonsense Mutation 24, 3'UTR 21, Splice Site 19, RNA 15, 5'UTR 11, In Frame Del 9, Splice Region 8.

Variants (750 of 1,015; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1933_1934del p.G645Wfs*12 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 53/211 reads (25%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- DMD | c.10453del p.L3485* | Frame Shift Del (DEL) | VAF 42/176 reads (24%) | catalogued as rs886043375, CD073610; ClinVar: pathogenic; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 90/213 reads (42%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- GRM6 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 23/458 reads (5%) | catalogued as rs62638214, CM050642, COSV99179689; ClinVar: pathogenic; called by muse, mutect2
- HPS1 | c.972dup p.M325Hfs*128 | Frame Shift Ins (INS) | VAF 40/154 reads (26%) | catalogued as rs281865082; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- HSD17B4 | c.1823_1824del p.R608Nfs*31 (on ENST00000414835 / NM_001199291.3; = p.R583Nfs*31 on NM_000414.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 61/256 reads (24%) | catalogued as rs1554068426; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 83/297 reads (28%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, varscan2
- MYO15A | c.1185dup p.E396Rfs*36 | Frame Shift Ins (INS) | VAF 70/325 reads (22%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PALB2 | c.839del p.N280Tfs*8 | Frame Shift Del (DEL) | VAF 101/494 reads (20%) | catalogued as rs1555461597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 24/118 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 226/454 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 187/479 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1439+8C>T | Splice Region (SNP) | VAF 37/104 reads (36%) | catalogued as rs199726798; called by muse, mutect2, varscan2
- ABRA | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 8/225 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.316); catalogued as rs1554641157, COSV61733688; called by muse, mutect2
- ACAN | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100718074; called by muse, mutect2, varscan2
- ADAMTS7 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 181/674 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs533435962, COSV101182998; called by muse, mutect2, varscan2
- ADCK5 | c.1268-2_1271del p.X423_splice | Splice Site (DEL) | VAF 4/85 reads (5%) | catalogued as rs1554861255, COSV100450851; called by muse*, mutect2
- ADCY6 | c.2642T>C p.F881S | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs963514206; called by muse, mutect2
- ADCY9 | c.193del p.R65Gfs*34 | Frame Shift Del (DEL) | VAF 47/215 reads (22%) | catalogued as COSV53574460; called by mutect2, pindel, varscan2
- AGAP9 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 284/1599 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs1343200106; called by muse, mutect2, varscan2
- AHNAK2 | c.6367G>A p.V2123I | Missense Mutation (SNP) | VAF 77/765 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.25); catalogued as rs369582582; called by muse, mutect2, varscan2
- ALDH4A1 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1363414092; called by muse, mutect2
- ALMS1 | c.11467C>T p.R3823W | Missense Mutation (SNP) | VAF 113/395 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as rs17848868; called by muse, mutect2, varscan2
- ANKRD31 | c.5323C>T p.L1775F | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57164729; called by muse, mutect2, varscan2
- AP1M1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs749149339, COSV52228455; called by muse, mutect2, varscan2
- AP2B1 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV51998626; called by muse, mutect2, varscan2
- APOB | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 33/459 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV51956225; called by muse, mutect2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 34/170 reads (20%) | catalogued as rs3215969; called by mutect2, varscan2
- ARAP1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs747974104; called by muse, mutect2, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 99/407 reads (24%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 75/280 reads (27%) | catalogued as rs965020534; called by mutect2, varscan2
- ARNT | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs778626866; called by muse, varscan2
- ASL | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 152/523 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as CM141231; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs746676748; called by mutect2, varscan2
- ATP10A | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV63513212; called by muse, mutect2, varscan2
- ATP2C1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146989; called by muse, mutect2, varscan2
- ATP2C2 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575721893; called by muse, mutect2, varscan2
- B9D2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 119/479 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs149500212; called by muse, mutect2, varscan2
- BACH2 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs576225753, COSV57590828; called by muse, mutect2, varscan2
- BMP1 | c.2713G>A p.V905M | Missense Mutation (SNP) | VAF 123/476 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs774390712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6279C>A p.H2093Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1566234239, COSV101204523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRF1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs200351753; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | catalogued as rs751388819; called by mutect2, varscan2
- C1QL2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs757745131; called by muse, mutect2, varscan2
- C3orf22 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | catalogued as rs752384324; called by muse, mutect2, varscan2
- CA1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.261); catalogued as rs1209853461; called by muse, mutect2, varscan2
- CACNA1D | c.3614C>T p.S1205L (on ENST00000350061 / NM_001128840.3; = p.S1225L on NM_000720.4) | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1183389331, COSV55454582; called by muse, mutect2, varscan2
- CAPN13 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV54432229; called by muse, mutect2, varscan2
- CCDC88C | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752834239, COSV66236062; called by muse, mutect2
- CD1B | c.527_528del p.V176Efs*6 | Frame Shift Del (DEL) | VAF 98/443 reads (22%) | catalogued as rs745615762; called by pindel, varscan2
- CD248 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 137/332 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768897237, COSV60936932; called by muse, mutect2, varscan2
- CDC45 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.961); catalogued as rs369554602; called by muse, mutect2, varscan2
- CDH1 | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV55732352; called by muse, mutect2
- CDHR2 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs113163991; called by muse, varscan2
- CEP89 | c.1388C>A p.S463Y | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59866442; called by muse, mutect2, varscan2
- CFAP157 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs752171285, COSV58852665, COSV58853238; called by muse, mutect2, varscan2
- CFAP65 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs952967820; called by muse, mutect2, varscan2
- CFHR3 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.923); catalogued as COSV66402846; called by muse, mutect2
- CHRD | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs748780200; called by muse, mutect2, varscan2
- CIC | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs111525814; called by muse, mutect2, varscan2
- CILK1 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs531691862; called by muse, mutect2, varscan2
- CLSTN3 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756068728, COSV56934949; called by muse, mutect2, varscan2
- COBLL1 | c.1337C>A p.P446Q (on ENST00000392717; = p.P408Q on NM_014900.5) | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV52065742; called by muse, mutect2, varscan2
- COL1A1 | c.1201-1G>T p.X401_splice | Splice Site (SNP) | VAF 87/585 reads (15%) | catalogued as rs72648321, CS982123; called by muse, mutect2, varscan2
- COL22A1 | c.2472del p.G825Vfs*8 | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | catalogued as COSV57350297; called by mutect2, pindel, varscan2
- COL23A1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs1196092245; called by muse, mutect2, varscan2
- COL2A1 | c.2678del p.P893Rfs*135 | Frame Shift Del (DEL) | VAF 48/195 reads (25%) | catalogued as CD104468; called by mutect2, pindel, varscan2
- COL6A5 | c.6608del p.L2203Wfs*11 (on ENST00000312481; = p.L2199Wfs*11 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 55/217 reads (25%) | catalogued as rs1231836053; called by mutect2, pindel, varscan2
- COLGALT1 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 30/459 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53107975; called by muse, mutect2
- CPSF2 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs1472674633; called by muse, mutect2
- CRYBG2 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.315); catalogued as rs1224733207; called by muse, varscan2
- CTSF | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 26/590 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs549988778, COSV59749783; called by muse, mutect2
- CXorf38 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 38/176 reads (22%) | catalogued as rs1318840802; called by muse, mutect2, varscan2
- CYP26B1 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as rs774836618, COSV50011631; called by muse, mutect2, varscan2
- CYP2A6 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs139639589; called by muse, mutect2, varscan2
- DAPK1 | c.4063C>A p.P1355T | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV100800662; called by muse, mutect2, varscan2
- DCDC1 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV60837264; called by muse, mutect2, varscan2
- DCTN1 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 102/410 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs147939455, COSV62621321; called by muse, varscan2
- DENND11 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1201732231; called by muse, mutect2, varscan2
- DEPDC5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760668998, CM164374, COSV56690476; called by muse, mutect2, varscan2
- DEXI | c.139A>G p.M47V | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs745621400, COSV59328878; called by muse, mutect2, varscan2
- DGUOK | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1558661819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIXDC1 | c.1991C>T p.A664V (on ENST00000440460 / NM_001037954.4; = p.A453V on NM_033425.4) | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1555178109; called by muse, mutect2, varscan2
- DNAH5 | c.8384G>A p.R2795Q | Missense Mutation (SNP) | VAF 100/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99443203; called by muse, mutect2, varscan2
- DNHD1 | c.9764G>A p.R3255Q | Missense Mutation (SNP) | VAF 159/619 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs188293407; called by muse, mutect2, varscan2
- DOCK7 | c.1412A>T p.N471I | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52023230; called by muse, mutect2, varscan2
- DOCK9 | c.2822C>T p.T941M (on ENST00000376460 / NM_001366676.2; = p.T942M on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as rs373900973; called by muse, mutect2, varscan2
- DOK3 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 108/456 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768009784, COSV57251720; called by muse, mutect2, varscan2
- DTX3 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs771323518, COSV99678290; called by muse, mutect2, varscan2
- EGLN2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349997342, COSV58279843; called by muse, mutect2, varscan2
- EGR3 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.821); catalogued as rs760574595; called by muse, mutect2, varscan2
- ELMO2 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.164); catalogued as rs1430245718; called by muse, mutect2, varscan2
- EME2 | c.569+5C>T | Splice Region (SNP) | VAF 38/400 reads (10%) | catalogued as rs376916673; called by muse, mutect2
- EMILIN1 | c.1386dup p.R463Afs*46 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | catalogued as rs753533275; called by mutect2, varscan2
- EP300 | c.6970dup p.H2324Pfs*55 | Frame Shift Ins (INS) | VAF 16/109 reads (15%) | catalogued as rs754418509; called by mutect2, varscan2
- EPAS1 | c.2402del p.P801Hfs*39 | Frame Shift Del (DEL) | VAF 77/294 reads (26%) | catalogued as COSV55386697; called by mutect2, pindel, varscan2
- EPHB3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1302758661; called by muse, mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 36/166 reads (22%) | catalogued as rs1309653898; called by mutect2, pindel, varscan2
- ESRRB | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 35/556 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs776797024, COSV55062218; called by muse, mutect2
- EXOC2 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 57/180 reads (32%) | catalogued as COSV57863822; called by muse, mutect2, varscan2
- FAM155B | c.715del p.A239Pfs*63 | Frame Shift Del (DEL) | VAF 87/368 reads (24%) | catalogued as COSV52935252; called by mutect2, pindel, varscan2
- FAM217B | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs570477685, COSV100674420, COSV62563924; called by muse, mutect2, varscan2
- FASN | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1445518429; called by muse, mutect2, varscan2
- FBXO24 | c.131del p.P44Qfs*63 (on ENST00000241071 / NM_033506.3; = p.P82Qfs*63 on NM_012172.5) | Frame Shift Del (DEL) | VAF 32/115 reads (28%) | catalogued as rs1311766618, COSV99575673; called by mutect2, pindel, varscan2
- FECH | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1389107704, COSV50490500; called by muse, mutect2, varscan2
- FGF3 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 64/338 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs903107353; called by muse, varscan2
- FLNC | c.3083A>G p.Y1028C | Missense Mutation (SNP) | VAF 88/451 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57968116; called by muse, mutect2, varscan2
- FMR1 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782089884; called by muse, mutect2, varscan2
- FOXD3 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64380134; called by muse, mutect2, varscan2
- FOXH1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 23/700 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs886062754; ClinVar: uncertain significance; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 40/172 reads (23%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FUBP1 | c.901dup p.I301Nfs*4 | Frame Shift Ins (INS) | VAF 54/230 reads (23%) | catalogued as rs1200882279; called by mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 56/168 reads (33%) | catalogued as rs756304971; called by mutect2, varscan2
- GAL3ST4 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs777290219; called by muse, mutect2, varscan2
- GATA3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 92/382 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs201730759, COSV100651218; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 20/130 reads (15%) | catalogued as rs763147690; called by mutect2, varscan2
- GJD2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 70/243 reads (29%) | catalogued as rs749647277, COSV51747639; called by muse, mutect2, varscan2
- GLYCTK | c.678dup p.L227Afs*68 | Frame Shift Ins (INS) | VAF 15/82 reads (18%) | catalogued as rs750821385; called by mutect2, pindel, varscan2
- GPA33 | c.691+1G>A p.X231_splice | Splice Site (SNP) | VAF 65/263 reads (25%) | catalogued as rs937977818, COSV63300760; called by muse, mutect2, varscan2
- GPAM | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778213301, COSV62082130; called by muse, mutect2, varscan2
- GPC4 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as rs939200503; called by muse, mutect2, varscan2
- GPHN | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.958); catalogued as COSV59495157; called by muse, mutect2, varscan2
- GRIN2C | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs756475049; called by muse, mutect2, varscan2
- H4C3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 18/317 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs778249149, COSV58091381; called by muse, mutect2
- H4C6 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1232796567; called by muse, mutect2, varscan2
- HAUS4 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as COSV99247174; called by muse, mutect2, varscan2
- HCFC1 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.971); catalogued as rs913518757; called by muse, mutect2, varscan2
- HCN4 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 108/617 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56086439; called by muse, mutect2, varscan2
- HDAC11 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs778634667, COSV55472341; called by muse, mutect2, varscan2
- HECA | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62770018; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs1449081007; called by mutect2, varscan2
- HIC2 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101335624; called by muse, mutect2
- HIPK2 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs776369379; called by muse, mutect2, varscan2
- HMGXB4 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs979637894; called by muse, mutect2, varscan2
- HRNR | c.5857C>G p.R1953G | Missense Mutation (SNP) | VAF 181/4010 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV64257294, COSV64261390; called by muse, mutect2
- HTR5A | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs114318906; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 156/590 reads (26%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, varscan2
- IGHG3 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 225/812 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as rs765975982; called by muse, mutect2, varscan2
- IL17RA | c.1387dup p.A463Gfs*48 | Frame Shift Ins (INS) | VAF 78/355 reads (22%) | catalogued as rs755093612; called by mutect2, pindel, varscan2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 62/278 reads (22%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- INPP4B | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53723746; called by muse, mutect2, varscan2
- INPPL1 | c.2927dup p.P977Tfs*7 | Frame Shift Ins (INS) | VAF 14/76 reads (18%) | catalogued as rs749079348; called by mutect2, varscan2
- IP6K1 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 106/432 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs1488584398; called by muse, mutect2, varscan2
- IRX1 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs745407739, COSV57361462; called by muse, mutect2, varscan2
- ITGB5 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766689337; called by muse, mutect2
- IVL | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 91/380 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as rs765004343; called by muse, mutect2, varscan2
- IZUMO2 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs372204859; called by muse, mutect2, varscan2
- JAK3 | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1178958564; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 218/631 reads (35%) | catalogued as rs763250381; called by mutect2, varscan2
- KCNA5 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52905875; called by muse, mutect2, varscan2
- KCNK17 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.336); catalogued as rs778003672; called by muse, mutect2
- KCNN2 | c.582+2T>C p.X194_splice (on ENST00000264773; = p.X406_splice on NM_021614.4) | Splice Site (SNP) | VAF 38/159 reads (24%) | catalogued as COSV99299314; called by muse, mutect2, varscan2
- KCNQ3 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs377725346, COSV66464287; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNU1 | c.3316G>A p.A1106T | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs769651908; called by muse, mutect2, varscan2
- KDM4A | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV64958950; called by muse, mutect2
- KIAA1109 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754271597; called by muse, mutect2, varscan2
- KL | c.2928del p.H977Tfs*10 | Frame Shift Del (DEL) | VAF 44/296 reads (15%) | catalogued as rs1430572004, COSV66308205; called by mutect2, pindel, varscan2
- KLHL34 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 53/244 reads (22%) | catalogued as COSV65280396; called by muse, mutect2, varscan2
- KMT2D | c.11515del p.Q3839Sfs*42 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | catalogued as rs1565778024, CM1413055, COSV56407863; called by mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 84/317 reads (26%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRT33B | c.72del p.S25Afs*17 | Frame Shift Del (DEL) | VAF 45/315 reads (14%) | catalogued as rs752320759; called by mutect2, pindel, varscan2
- KRTAP10-9 | c.759del p.T254Pfs*127 | Frame Shift Del (DEL) | VAF 103/418 reads (25%) | catalogued as rs1555934894; called by mutect2, pindel, varscan2
- KRTAP26-1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100860520; called by muse, mutect2, varscan2
- LAMB4 | c.3661A>G p.R1221G | Missense Mutation (SNP) | VAF 80/361 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1316652662; called by muse, mutect2, varscan2
- LETM1 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.029); catalogued as rs577892044; called by muse, mutect2, varscan2
- LGALS4 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.221); catalogued as rs985583413; called by muse, mutect2, varscan2
- LRATD2 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 99/366 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs775146913; called by muse, mutect2, varscan2
- LRFN3 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV55818849; called by muse, mutect2, varscan2
- LRIT3 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs769022952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K1 | c.4077T>A p.Y1359* | Nonsense Mutation (SNP) | VAF 49/311 reads (16%) | catalogued as COSV99063955; called by muse, mutect2, varscan2
- MAPK6 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV55931535; called by muse, mutect2
- MARK2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761380187, COSV59286299; called by muse, mutect2, varscan2
- MCUB | c.1005G>C p.K335N | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1400868443; called by muse, mutect2, varscan2
- MED12 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866469400, COSV100378827; called by muse, mutect2, varscan2
- MEGF10 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 79/574 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as rs568794084, COSV57245707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFAP4 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs769104779, COSV100218729; called by muse, mutect2, varscan2
- MID2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs1254056001, COSV53311438; called by muse, mutect2, varscan2
- MIDEAS | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV54098459; called by muse, mutect2, varscan2
- MOV10L1 | c.1426del p.T476Lfs*5 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as rs777769041; called by mutect2, pindel
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MPRIP | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs944814693, COSV100505198; called by muse, mutect2
- MSC | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs750993756, COSV57696248; called by muse, mutect2, varscan2
- MTG2 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV63693862; called by muse, mutect2, varscan2
- MTREX | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57926819; called by muse, mutect2, varscan2
- MUC16 | c.1931C>T p.T644M | Missense Mutation (SNP) | VAF 90/347 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs546209001, COSV67471740; called by muse, mutect2, varscan2
- MUC5B | c.12005C>A p.P4002H | Missense Mutation (SNP) | VAF 76/397 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.712); catalogued as rs1441939444; called by muse, mutect2, varscan2
- MYH11 | c.5092G>A p.A1698T | Missense Mutation (SNP) | VAF 13/417 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as rs187172581; ClinVar: uncertain significance; called by muse, mutect2
- MYO10 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as rs764152071; called by muse, mutect2, varscan2
- MYOM1 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370063864; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAV2 | c.2026G>A p.V676I (on ENST00000396087 / NM_001244963.2; = p.V653I on NM_145117.5) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as rs141668055; called by muse, mutect2, varscan2
- NDE1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs147283674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEXMIF | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs752577352; called by muse, mutect2, varscan2
- NKRF | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs1317795250; called by muse, mutect2, varscan2
- NLRP12 | c.2188del p.V730* | Frame Shift Del (DEL) | VAF 99/406 reads (24%) | catalogued as rs771632319; called by mutect2, pindel, varscan2
- NMNAT2 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1188292900, COSV54267602; called by muse, mutect2
- NOC4L | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1314407747; called by muse, mutect2, varscan2
- NOXA1 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.235); catalogued as COSV58163433; called by muse, mutect2
- NPR1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs61737934; called by muse, mutect2, varscan2
- NR2F6 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203844080; called by muse, mutect2, varscan2
- NRP2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs764826189, COSV55924199, COSV55927948; called by muse, mutect2, varscan2
- NRXN2 | c.1987A>G p.I663V | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs373542632; called by muse, mutect2, varscan2
- NTF4 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs776576559; called by muse, mutect2, varscan2
- NTRK1 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV62324787; called by muse, mutect2
- NUDT16L1 | c.601_603del p.K201del | In Frame Del (DEL) | VAF 47/235 reads (20%) | catalogued as rs1283990748; called by pindel, varscan2
- OBSCN | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs1020884065; called by muse, mutect2, varscan2
- OR13H1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs867787716; called by muse, mutect2, varscan2
- OR1B1 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs370410299; called by muse, mutect2, varscan2
- OR4X1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 101/369 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as rs568260658, COSV100186677, COSV60723069; called by muse, mutect2, varscan2
- OR5A1 | c.317dup p.F107Lfs*8 | Frame Shift Ins (INS) | VAF 43/159 reads (27%) | catalogued as rs755323345; called by mutect2, varscan2
- PANX2 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs1226456227, COSV99348678; called by muse, mutect2, varscan2
- PASK | c.1811del p.G604Afs*4 | Frame Shift Del (DEL) | VAF 91/331 reads (27%) | catalogued as rs769655744; called by mutect2, varscan2
- PBRM1 | c.5024G>A p.R1675Q (on ENST00000296302 / NM_001366071.2; = p.R1568Q on NM_018313.5) | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs200304933; called by muse, varscan2
- PCDH10 | c.360del p.S121Lfs*7 | Frame Shift Del (DEL) | VAF 58/234 reads (25%) | catalogued as rs759095467; called by pindel, varscan2
- PCDHA13 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 70/408 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554181269, COSV56504468; called by muse, mutect2, varscan2
- PDE10A | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 17/352 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1408673805, COSV64835622; called by muse, mutect2
- PDGFRB | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55807655; called by muse, mutect2
- PEG3 | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1260748392; called by muse, mutect2, varscan2
- PGBD1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs199718652; called by muse, mutect2, varscan2
- PKD1L2 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs778394051; called by muse, mutect2, varscan2
- PKP2 | c.2129C>T p.T710M | Missense Mutation (SNP) | VAF 107/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397517016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G4D | c.2044-3dup | Splice Region (INS) | VAF 39/182 reads (21%) | catalogued as rs764558564; called by mutect2, varscan2
- PLAU | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs201687228, COSV65641339; called by muse, mutect2, varscan2
- PLCXD1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); catalogued as rs758660203, COSV67541529; called by muse, mutect2, varscan2
- PLEKHN1 | c.988_990del p.K330del (on ENST00000379409; = p.K278del on NM_032129.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 29/122 reads (24%) | catalogued as rs768926690; called by mutect2, pindel, varscan2
- PLSCR5 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV71649001; called by muse, mutect2, varscan2
- POLR3E | c.1774C>A p.L592M | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.343); catalogued as COSV55403672; called by muse, mutect2, varscan2
- POTEE | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 114/603 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs781648859; called by muse, mutect2, varscan2
- PPL | c.4313G>A p.R1438H | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs771636228; called by muse, mutect2, varscan2
- PPP1R18 | c.647G>T p.R216I | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as rs1469774467; called by muse, mutect2, varscan2
- PPT2 | c.814del p.A272Pfs*2 | Frame Shift Del (DEL) | VAF 60/224 reads (27%) | catalogued as COSV61353901, COSV61353944; called by mutect2, pindel, varscan2
- PSME4 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs745428986; called by muse, mutect2, varscan2
- PSPN | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs533804498; called by muse, mutect2, varscan2
- PTPRQ | c.2497del p.Q833Kfs*18 (on ENST00000616559; = p.Q791Kfs*18 on NM_001145026.2) | Frame Shift Del (DEL) | VAF 36/217 reads (17%) | catalogued as rs935928481, COSV57034264; called by mutect2, pindel, varscan2
- RASGEF1B | c.967del p.T323Lfs*5 | Frame Shift Del (DEL) | VAF 47/291 reads (16%) | catalogued as rs765006689; called by mutect2, varscan2
- RASSF4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200147715, COSV53584646; called by muse, mutect2, varscan2
- RB1 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 58/268 reads (22%) | catalogued as COSV57303708; called by muse, mutect2, varscan2
- RERE | c.3249del p.S1084Rfs*173 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | catalogued as rs745806637; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RIC3 | c.326dup p.L109Ffs*9 | Frame Shift Ins (INS) | VAF 26/219 reads (12%) | catalogued as rs746684945; called by mutect2, varscan2
- RP1L1 | c.1534C>A p.L512M | Missense Mutation (SNP) | VAF 29/452 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as COSV101223689; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 73/248 reads (29%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPTOR | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs374764141; called by muse, mutect2, varscan2
- RREB1 | c.4064C>T p.A1355V | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs913367093, COSV58558817; called by muse, mutect2, varscan2
- RSF1 | c.4007G>A p.S1336N | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs371055212; called by muse, mutect2, varscan2
- RYR1 | c.668A>G p.H223R | Missense Mutation (SNP) | VAF 146/535 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766836202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBNO2 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362285005; called by muse, mutect2, varscan2
- SCML1 | c.294G>A p.W98* (on ENST00000380041 / NM_001037540.3; = p.W71* on NM_006746.6) | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV101193948; called by muse, mutect2, varscan2
- SCN9A | c.1129del p.T377Pfs*3 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | catalogued as COSV57602408; called by mutect2, pindel, varscan2
- SCNN1D | c.539del p.R180Pfs*17 (on ENST00000338555; = p.R344Pfs*17 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 46/236 reads (19%) | catalogued as rs1326165103, COSV57640659; called by mutect2, pindel, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 29/132 reads (22%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SDCCAG8 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs577345357; called by muse, mutect2
- SETD2 | c.6781G>C p.A2261P | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1388854944; called by muse, mutect2
- SFXN3 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs538356053, COSV56520303; called by muse, mutect2
- SGSM2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369769471; called by muse, mutect2, varscan2
- SH2B3 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 130/413 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs748009957, COSV57983966; called by muse, mutect2, varscan2
- SH2D3A | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs777699573, COSV55585229; called by muse, mutect2, varscan2
- SHISA9 | c.131del p.G44Afs*72 | Frame Shift Del (DEL) | VAF 45/269 reads (17%) | catalogued as COSV101376111; called by mutect2, pindel, varscan2
- SLC15A2 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99815411; called by muse, mutect2, varscan2
- SLC15A4 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57160888; called by muse, mutect2
- SLC23A2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100594688; called by muse, mutect2, varscan2
- SLC25A38 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 109/428 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1447803374; called by muse, mutect2, varscan2
- SLC38A8 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1040079527, COSV55305326; called by muse, mutect2
- SLC6A3 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs369923764, COSV104373642; called by muse, mutect2, varscan2
- SLC9C2 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV100876552; called by muse, mutect2, varscan2
- SLTM | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267604274; called by muse, mutect2
- SMO | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs747136892; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 37/186 reads (20%) | catalogued as rs768873484; called by mutect2, varscan2
- SOBP | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454319273, COSV57996201; called by muse, mutect2, varscan2
- SORCS1 | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV53883402; called by muse, mutect2, varscan2
- SORT1 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.329); catalogued as COSV99860389; called by muse, mutect2
- SP4 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as rs763993457, COSV99753814; called by muse, mutect2, varscan2
- SPATA19 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs554707761; called by muse, mutect2, varscan2
- SPDYE5 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 100/606 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs1554483083; called by muse, mutect2, varscan2
- SPHKAP | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316923941, COSV60880688; called by muse, mutect2, varscan2
- SPTLC3 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs201373651, COSV100983167; called by muse, mutect2
- STYK1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775598308; called by muse, mutect2, varscan2
- SULF1 | c.461del p.P154Lfs*9 | Frame Shift Del (DEL) | VAF 50/202 reads (25%) | catalogued as COSV52691636; called by mutect2, pindel, varscan2
- SULT1C2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as rs1191499679, COSV52267739; called by muse, mutect2
- SUSD2 | c.2438G>A p.G813D | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1317926536; called by muse, mutect2, varscan2
- SVEP1 | c.2722C>T p.P908S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs1376020385; called by muse, mutect2
- SYT16 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as rs763887935, COSV70857129; called by muse, mutect2
- TASP1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as rs780787096, COSV61815608; called by muse, mutect2, varscan2
- TBC1D31 | c.1893del p.H632Tfs*8 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs768246273; called by mutect2, varscan2
- TBCD | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 117/431 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as rs757289175; called by muse, mutect2, varscan2
- TCHH | c.4961G>A p.R1654H | Missense Mutation (SNP) | VAF 186/689 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as rs775186687, COSV100914909; called by muse, mutect2, varscan2
- TEX55 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV99817442; called by muse, mutect2, varscan2
- TF | c.2062T>C p.S688P | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs139122360; called by muse, mutect2, varscan2
- THBS2 | c.3370A>G p.R1124G | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100827996; called by muse, mutect2, varscan2
- THSD7A | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV70263607; called by muse, mutect2, varscan2
- TMEM200C | c.62del p.P21Qfs*22 | Frame Shift Del (DEL) | VAF 48/237 reads (20%) | catalogued as rs756579008; called by mutect2, pindel, varscan2
- TMEM267 | c.488A>G p.H163R | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs1197347625; called by muse, mutect2, varscan2
- TNRC18 | c.6118C>T p.R2040C | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1190510466, COSV68162634; called by muse, mutect2, varscan2
- TOP3B | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757937448; called by muse, mutect2, varscan2
- TOPBP1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV53434042, COSV53438315; called by muse, mutect2, varscan2
- TP53BP1 | c.2130del p.E711Nfs*12 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as rs1375740992, COSV55498775; called by mutect2, varscan2
- TRIM26 | c.845del p.K282Rfs*16 | Frame Shift Del (DEL) | VAF 52/191 reads (27%) | catalogued as rs1271434984; called by mutect2, varscan2
- TRPM2 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV55973015; called by muse, mutect2
- TRPM2 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138507862; called by muse, mutect2, varscan2
- TTC7A | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 91/324 reads (28%) | catalogued as rs779549457, COSV99766400; called by muse, mutect2, varscan2
- TTN | c.35116C>T p.P11706S (on ENST00000591111; = p.P10779S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/178 reads (21%) | PolyPhen benign (0.23); catalogued as rs766710373; called by muse, mutect2, varscan2
- U2SURP | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1343149169; called by muse, mutect2, varscan2
- UBE2E3 | c.601T>C p.W201R | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66587037; called by muse, mutect2, varscan2
- UBXN6 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs375533590; called by muse, mutect2, varscan2
- UCN3 | c.311G>T p.R104M | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV66824272; called by muse, mutect2, varscan2
- ULK3 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 65/268 reads (24%) | catalogued as rs1049069646, COSV51513020; called by muse, mutect2, varscan2
- USP13 | c.1854del p.L619Yfs*15 | Frame Shift Del (DEL) | VAF 30/127 reads (24%) | catalogued as rs1333558391; called by mutect2, pindel, varscan2
- VASP | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV55606272; called by muse, mutect2, varscan2
- VGF | c.1766_1768del p.E589del | In Frame Del (DEL) | VAF 47/198 reads (24%) | catalogued as rs781368212; called by pindel, varscan2
- VWA1 | c.94dup p.R32Pfs*64 | Frame Shift Ins (INS) | VAF 28/119 reads (24%) | catalogued as rs761604051; called by mutect2, pindel, varscan2
- WDR75 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as rs562776153, COSV59105923; called by muse, varscan2
- WFIKKN1 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761966291; called by muse, mutect2, varscan2
- WFIKKN2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs777517936, COSV60957989; called by muse, mutect2, varscan2
- WNK2 | c.6634G>A p.A2212T (on ENST00000297954 / NM_001282394.1; = p.A2175T on NM_006648.3) | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.029); catalogued as rs1313135952; called by muse, mutect2, varscan2
- XPO5 | c.2072A>G p.D691G | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54827331; called by muse, mutect2, varscan2
- XRN2 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147104098; called by muse, mutect2, varscan2
- ZBTB38 | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 89/331 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.959); catalogued as rs750935587; called by muse, mutect2, varscan2
- ZC3H18 | c.2037dup p.R680Qfs*14 | Frame Shift Ins (INS) | VAF 24/148 reads (16%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H18 | c.2812G>A p.V938M | Missense Mutation (SNP) | VAF 209/723 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56325304; called by muse, mutect2, varscan2
- ZFP28 | c.64dup p.R22Pfs*73 | Frame Shift Ins (INS) | VAF 38/175 reads (22%) | catalogued as rs905249572; called by mutect2, pindel, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 33/137 reads (24%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 76/256 reads (30%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF185 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs782175139, COSV59275154; called by muse, mutect2, varscan2
- ZNF19 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV55508101; called by muse, mutect2, varscan2
- ZNF254 | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as rs1002089714; called by muse, mutect2, varscan2
- ZNF285 | c.1081A>C p.I361L | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.539); catalogued as COSV58411624; called by muse, mutect2, varscan2
- ZNF324B | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243934490; called by muse, mutect2
- ZNF335 | c.4006G>A p.V1336I | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs372687838, COSV100533477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF366 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as rs367714370; called by muse, mutect2, varscan2
- ZNF471 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs142290015; called by muse, mutect2, varscan2
- ZNF483 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as rs201645923, COSV58514469; called by muse, mutect2, varscan2
- ZNF566 | c.927del p.K309Nfs*139 | Frame Shift Del (DEL) | VAF 26/197 reads (13%) | catalogued as rs750272831, COSV67573844; called by mutect2, pindel, varscan2
- ZNF598 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs370797572; called by muse, mutect2, varscan2
- ZNF616 | c.1336T>C p.Y446H | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs752968005; called by muse, mutect2, varscan2
- ZNF786 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV60277595; called by muse, mutect2
- ZNF827 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs759748128; called by muse, mutect2, varscan2
- ZNF839 | c.1193dup p.A400Sfs*4 (on ENST00000558850 / NM_001267827.1; = p.A516Sfs*4 on NM_018335.5) | Frame Shift Ins (INS) | VAF 32/155 reads (21%) | catalogued as rs760216872; called by mutect2, pindel, varscan2
- ZNF93 | c.556T>C p.S186P | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV59375801; called by muse, mutect2, varscan2
- AACS | c.916-4G>A | Splice Region (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- ABCA4 | c.2096C>T p.T699I | Missense Mutation (SNP) | VAF 85/437 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ABCA7 | c.3947A>G p.H1316R | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB7 | c.2138A>G p.Q713R (on ENST00000373394 / NM_001271696.3; = p.Q714R on NM_004299.6) | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCC4 | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 138/518 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ACAD9 | c.1712_1714del p.F571del | In Frame Del (DEL) | VAF 110/646 reads (17%) | called by mutect2, pindel, varscan2
- ACTR5 | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ADAMTS17 | c.1578G>A p.W526* | Nonsense Mutation (SNP) | VAF 48/193 reads (25%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.2626del p.S876Vfs*35 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.2443A>G p.K815E | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ADCY1 | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- ADCY3 | c.3023_3024dup p.R1009Sfs*16 | Frame Shift Ins (INS) | VAF 22/104 reads (21%) | called by mutect2, varscan2
- ADGRV1 | c.8194G>T p.G2732C | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AEBP2 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AGO2 | c.1183C>A p.R395S | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AGO2 | c.51del p.I18Sfs*121 | Frame Shift Del (DEL) | VAF 42/186 reads (23%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.6505del p.I2169* (on ENST00000366508; = p.I2143* on NM_015446.5) | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel
- AHRR | c.16del p.E6Sfs*71 | Frame Shift Del (DEL) | VAF 118/436 reads (27%) | called by mutect2, pindel, varscan2
- ALDH1A3 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALX1 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ANAPC1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ANGEL2 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4215del p.K1405Nfs*10 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD27 | c.2284del p.L762Sfs*3 | Frame Shift Del (DEL) | VAF 50/249 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD33 | c.12C>A p.C4* (on ENST00000340970 / NM_001304459.2; = p.C139* on NM_182608.4) | Nonsense Mutation (SNP) | VAF 56/171 reads (33%) | called by muse, mutect2, varscan2
- ANO7 | c.2618C>A p.P873H (on ENST00000274979; = p.P819H on NM_001370694.2) | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQR | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ARMC4 | c.1730del p.G577Vfs*9 | Frame Shift Del (DEL) | VAF 54/207 reads (26%) | called by mutect2, pindel, varscan2
- ARNTL | c.1195del p.I399Lfs*26 (on ENST00000403290 / NM_001297719.2; = p.I398Lfs*26 on NM_001178.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- ASB18 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ASCC1 | c.955+2T>C p.X319_splice (on ENST00000342444 / NM_001369085.1; = p.X291_splice on NM_001198798.2 and 8 other RefSeq transcripts) | Splice Site (SNP) | VAF 64/271 reads (24%) | called by muse, mutect2, varscan2
- ASPM | c.4916T>C p.L1639P | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATRX | c.1116A>T p.K372N | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- BEST2 | c.1277A>G p.E426G | Missense Mutation (SNP) | VAF 172/709 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- C15orf39 | c.1805C>A p.A602D | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- C19orf44 | c.698del p.N233Tfs*26 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel
- C19orf57 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- C1QL3 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); called by muse, mutect2
- C2CD4D | c.657dup p.Q220Afs*137 | Frame Shift Ins (INS) | VAF 42/179 reads (23%) | called by mutect2, pindel, varscan2
- C2orf81 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- C6orf132 | c.3032C>A p.S1011Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1E | c.4564del p.S1522Pfs*6 | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | called by mutect2, pindel, varscan2
- CAD | c.1843-2A>G p.X615_splice | Splice Site (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- CAPN13 | c.1612T>C p.F538L | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARD16 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 89/269 reads (33%) | called by muse, mutect2, varscan2
- CBX1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBX5 | c.316_317del p.K106Efs*6 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | called by mutect2, pindel, varscan2
- CBX7 | c.364del p.A122Hfs*99 | Frame Shift Del (DEL) | VAF 47/179 reads (26%) | called by mutect2, pindel, varscan2
- CCDC138 | c.852del p.K284Nfs*3 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel
- CCDC181 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CCDC68 | c.806del p.N269Ifs*3 | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | called by mutect2, pindel, varscan2
- CCDC88B | c.3963G>T p.K1321N | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCSAP | c.607_609del p.N203del | In Frame Del (DEL) | VAF 18/179 reads (10%) | called by mutect2, pindel
- CDC42BPB | c.772T>A p.Y258N | Missense Mutation (SNP) | VAF 99/482 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC73 | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDHR3 | c.1463A>C p.K488T | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CDK10 | c.413C>T p.A138V (on ENST00000353379 / NM_052988.5; = p.A67V on NM_052987.4) | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CDK5RAP1 | c.1690G>A p.V564I (on ENST00000357886 / NM_001365728.1; = p.V550I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CENPI | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CERS3 | c.1112C>A p.A371D | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP221 | c.1179del p.E394Sfs*15 | Frame Shift Del (DEL) | VAF 29/179 reads (16%) | called by mutect2, pindel, varscan2
- CFAP221 | c.2134-1G>T p.X712_splice | Splice Site (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- CFAP70 | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFHR5 | c.1550del p.N517Ifs*5 | Frame Shift Del (DEL) | VAF 28/137 reads (20%) | called by mutect2, pindel, varscan2
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 80/368 reads (22%) | called by mutect2, pindel, varscan2
- CLPTM1 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CLTCL1 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CNOT3 | c.1391del p.P464Hfs*39 | Frame Shift Del (DEL) | VAF 44/195 reads (23%) | called by mutect2, pindel, varscan2
- COL24A1 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CRTC2 | c.1852_1854del p.I618del | In Frame Del (DEL) | VAF 11/90 reads (12%) | called by pindel, varscan2
- CRX | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CRY1 | c.1547A>G p.Y516C | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CSGALNACT1 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CTNNA3 | c.2669G>T p.R890I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, varscan2
- CTSF | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CXorf65 | c.413del p.P138Lfs*56 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- DAG1 | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DBX2 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCAF17 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 25/387 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.372); called by muse, mutect2
- DCHS1 | c.4626C>G p.N1542K | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- DGKH | c.601T>A p.S201T | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- DISP3 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP5 | c.874A>G p.N292D | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DMD | c.8986A>G p.N2996D | Missense Mutation (SNP) | VAF 43/437 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- DNAH3 | c.5169G>T p.L1723F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DOCK1 | c.5401C>T p.P1801S | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DOK7 | c.437dup p.A147Gfs*10 | Frame Shift Ins (INS) | VAF 153/689 reads (22%) | called by mutect2, pindel, varscan2
- DROSHA | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); called by muse, mutect2
- DUOX1 | c.3838G>A p.A1280T | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- DYNC2H1 | c.3340T>C p.F1114L | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- E2F7 | c.146dup p.N49Kfs*2 | Frame Shift Ins (INS) | VAF 32/162 reads (20%) | called by mutect2, pindel
- EBF4 | c.768del p.C257Afs*63 (on ENST00000609451; = p.C253Afs*63 on NM_001110514.1) | Frame Shift Del (DEL) | VAF 68/252 reads (27%) | called by mutect2, pindel, varscan2
- ECEL1 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EDNRA | c.1133A>C p.N378T | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- EFCAB1 | c.313dup p.M105Nfs*6 | Frame Shift Ins (INS) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- EFNB3 | c.991del p.Q331Rfs*39 | Frame Shift Del (DEL) | VAF 101/312 reads (32%) | called by mutect2, pindel, varscan2
- EHD2 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EIF3L | c.1656+5G>T | Splice Region (SNP) | VAF 61/219 reads (28%) | called by muse, mutect2, varscan2
- ELAC2 | c.116A>C p.H39P | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EMILIN3 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- EML5 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EWSR1 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EXOC8 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 74/364 reads (20%) | called by muse, mutect2, varscan2
- FABP6 | c.29T>A p.V10E | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- FAM122B | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- FAM135B | c.3581T>C p.L1194S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM171A1 | c.1386G>T p.E462D | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2
- FAM200B | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM20A | c.1053del p.R352Gfs*30 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel
- FAT4 | c.6641C>T p.A2214V | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FAU | c.277-1G>T p.X93_splice | Splice Site (SNP) | VAF 61/201 reads (30%) | called by muse, mutect2, varscan2
- FBXW5 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FCRL3 | c.1065A>T p.R355S | Missense Mutation (SNP) | VAF 108/377 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, varscan2
- FLNA | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FMN2 | c.1490del p.G497Efs*171 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- FMN2 | c.4805C>G p.S1602* | Nonsense Mutation (SNP) | VAF 45/200 reads (23%) | called by muse, mutect2, varscan2
- FZD10 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAGE12J | c.5G>C p.S2T | Missense Mutation (SNP) | VAF 78/862 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); called by muse, mutect2
- GALNT18 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA5 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 106/346 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- GATA6 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- GATB | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GBF1 | c.4822G>A p.A1608T (on ENST00000369983 / NM_001377137.1; = p.A1607T on NM_004193.3) | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GFM1 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 142/442 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRA4 | c.1154G>T p.R385I | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GOLGA1 | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- GOLGA8J | c.1428del p.E477Nfs*103 | Frame Shift Del (DEL) | VAF 68/534 reads (13%) | called by mutect2, pindel, varscan2
- GPBAR1 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GPC6 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPLD1 | c.427A>G p.R143G | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GPR3 | c.485dup p.G163Rfs*109 | Frame Shift Ins (INS) | VAF 57/250 reads (23%) | called by mutect2, pindel, varscan2
- GPRIN2 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIA2 | c.2178G>T p.E726D | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIP2 | c.1260G>T p.K420N (on ENST00000619221; = p.K323N on NM_001080423.4) | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- GSTT2B | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- GZMH | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HAPLN2 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HES5 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HEXB | c.772-1G>T p.X258_splice | Splice Site (SNP) | VAF 60/258 reads (23%) | called by muse, mutect2, varscan2
- HIPK1 | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- HIPK3 | c.1300del p.C434Afs*13 | Frame Shift Del (DEL) | VAF 27/146 reads (18%) | called by mutect2, pindel, varscan2
- HMGCLL1 | c.379del p.V127Yfs*10 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by pindel, varscan2
- HNF4A | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 135/502 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- HPD | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 75/477 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HRC | c.71del p.P24Rfs*3 | Frame Shift Del (DEL) | VAF 70/296 reads (24%) | called by mutect2, pindel, varscan2
- HSD3B7 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 96/566 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ICAM1 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IFIH1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-5 | c.290del p.N97Tfs*7 | Frame Shift Del (DEL) | VAF 139/542 reads (26%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 94/410 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- IGKV1-9 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 185/649 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGSF8 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 32/718 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- INPPL1 | c.1322del p.N441Tfs*2 | Frame Shift Del (DEL) | VAF 52/138 reads (38%) | called by mutect2, pindel, varscan2
- INSRR | c.2102dup p.L702Afs*13 | Frame Shift Ins (INS) | VAF 37/296 reads (13%) | called by mutect2, pindel, varscan2
- JAG2 | c.2220dup p.G741Rfs*66 | Frame Shift Ins (INS) | VAF 70/260 reads (27%) | called by mutect2, varscan2
- KCNJ2 | c.1211dup p.D405* | Frame Shift Ins (INS) | VAF 87/361 reads (24%) | called by mutect2, pindel, varscan2
- KDM2A | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM2A | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 161/480 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KDM5C | c.4315G>T p.E1439* | Nonsense Mutation (SNP) | VAF 29/468 reads (6%) | called by muse, mutect2
- KIAA1549 | c.2380C>A p.H794N | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KLHL12 | c.1560del p.R521Dfs*14 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel
- KLHL31 | c.557del p.N186Mfs*24 | Frame Shift Del (DEL) | VAF 88/374 reads (24%) | called by mutect2, pindel, varscan2
- KLRF2 | c.467del p.L156* | Frame Shift Del (DEL) | VAF 27/124 reads (22%) | called by mutect2, pindel, varscan2
- KMT2B | c.5276+1G>T p.X1759_splice | Splice Site (SNP) | VAF 92/370 reads (25%) | called by muse, mutect2, varscan2
- KNDC1 | c.4258del p.R1420Efs*45 | Frame Shift Del (DEL) | VAF 50/188 reads (27%) | called by mutect2, pindel, varscan2
- KRT18 | c.820_822del p.Q274del | In Frame Del (DEL) | VAF 81/356 reads (23%) | called by pindel, varscan2
- KRTAP29-1 | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LAMB3 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LENG8 | c.36T>A p.D12E | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LINC00636 | n.229+1G>A | Splice Site (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- LPAR6 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- LRRC7 | c.1515dup p.E506Rfs*3 (on ENST00000651989 / NM_001370785.2; = p.E473Rfs*3 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 25/166 reads (15%) | called by mutect2, pindel, varscan2
- LRRK2 | c.5923G>A p.A1975T | Missense Mutation (SNP) | VAF 121/419 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- MAGEB16 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MALRD1 | c.3532G>A p.V1178M | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MAOB | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAP1A | c.8245del p.E2749Rfs*5 | Frame Shift Del (DEL) | VAF 62/279 reads (22%) | called by mutect2, pindel, varscan2
- MARCKS | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MARK3 | c.1121G>T p.S374I | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MDM4 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED16 | c.2413A>G p.T805A | Missense Mutation (SNP) | VAF 123/435 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- MGAM | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MN1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MPP7 | c.1376del p.N459Tfs*13 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | called by mutect2, pindel, varscan2
- MRPL45 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MSL1 | c.349del p.E117Sfs*86 | Frame Shift Del (DEL) | VAF 48/193 reads (25%) | called by mutect2, pindel, varscan2
- MTERF1 | c.1159del p.R387Dfs*6 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- MUC12 | c.820G>A p.A274T (on ENST00000379442; = p.A131T on NM_001164462.1) | Missense Mutation (SNP) | VAF 154/593 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- MUC13 | c.438del p.T147Pfs*22 | Frame Shift Del (DEL) | VAF 79/286 reads (28%) | called by mutect2, pindel, varscan2
- MUC16 | c.39035C>A p.P13012Q | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- MUC16 | c.3521A>G p.Q1174R | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- MYO18B | c.5911G>A p.V1971I | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2
- MYO3B | c.2840T>C p.V947A | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MZF1 | c.1891G>T p.G631C | Missense Mutation (SNP) | VAF 50/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NACAD | c.3649C>T p.P1217S | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.354); called by muse, mutect2
- NCR2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NEBL | c.2611+2T>C p.X871_splice | Splice Site (SNP) | VAF 29/291 reads (10%) | called by muse, mutect2
- NEK7 | c.192del p.V65Cfs*6 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by mutect2, pindel
- NIM1K | c.1254del p.S420Pfs*7 | Frame Shift Del (DEL) | VAF 39/168 reads (23%) | called by mutect2, pindel, varscan2
- NOS2 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRBP2 | c.582G>A p.V194= | Splice Region (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- NSD2 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NTM | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NTRK1 | c.428+1G>A p.X143_splice | Splice Site (SNP) | VAF 22/652 reads (3%) | called by muse, mutect2
- NUP42 | c.212del p.G71Afs*51 | Frame Shift Del (DEL) | VAF 58/223 reads (26%) | called by mutect2, pindel, varscan2
- NUTM2D | c.2012G>T p.R671M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by mutect2, varscan2
- NYAP1 | c.1328dup p.A444Cfs*122 | Frame Shift Ins (INS) | VAF 12/85 reads (14%) | called by mutect2, varscan2
- OR51B4 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR5H14 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6C70 | c.757T>C p.C253R | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OSBPL5 | c.188del p.P63Rfs*59 | Frame Shift Del (DEL) | VAF 37/127 reads (29%) | called by mutect2, pindel, varscan2
- P3H4 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PAK4 | c.1093A>G p.N365D | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PARP8 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, varscan2
- PATJ | c.5351C>T p.T1784I | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PBX1 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 13/432 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PCDH7 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA8 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PGR | c.1756_1757dup p.S586Rfs*64 | Frame Shift Ins (INS) | VAF 105/359 reads (29%) | called by mutect2, pindel, varscan2
- PITPNM2 | c.1621del p.D541Tfs*9 | Frame Shift Del (DEL) | VAF 35/305 reads (11%) | called by mutect2, pindel, varscan2
- PITRM1 | c.2771G>T p.R924M | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLK1 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLK | c.1432_1434del p.V478del | In Frame Del (DEL) | VAF 12/94 reads (13%) | called by pindel, varscan2
- POLR1A | c.3741G>T p.R1247S | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU2F2 | c.686G>A p.G229D (on ENST00000526816 / NM_001207025.3; = p.G213D on NM_002698.5) | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPDPF | c.57C>T p.R19= | Splice Region (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.967-1G>T p.X323_splice (on ENST00000318304 / NM_177444.3; = p.X303_splice on NM_003622.4) | Splice Site (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- PPP4C | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 35/194 reads (18%) | called by muse, mutect2, varscan2
- PRRT2 | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSD2 | c.772del p.D258Mfs*13 | Frame Shift Del (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- PSKH1 | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PSMA3 | c.723+1G>A p.X241_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- PTPA | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- PTPN3 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PTPRE | c.420+2T>C p.X140_splice | Splice Site (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- PTPRS | c.2027del p.P676Rfs*134 | Frame Shift Del (DEL) | VAF 75/427 reads (18%) | called by mutect2, pindel, varscan2
- QPRT | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB11FIP1 | c.178A>T p.S60C | Missense Mutation (SNP) | VAF 156/610 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RAMP3 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- RANBP2 | c.7628C>T p.S2543F | Missense Mutation (SNP) | VAF 211/903 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAPGEF1 | c.2642A>G p.Q881R | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- RB1 | c.610dup p.X204_splice | Splice Site (INS) | VAF 44/208 reads (21%) | called by mutect2, pindel, varscan2
- RBM6 | c.293del p.G98Efs*56 | Frame Shift Del (DEL) | VAF 63/190 reads (33%) | called by mutect2, pindel, varscan2
- RBP3 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 15/474 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.206); called by muse, mutect2
- RFPL1 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- RGL3 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 139/491 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RIF1 | c.2074dup p.S692Ffs*15 | Frame Shift Ins (INS) | VAF 51/237 reads (22%) | called by mutect2, pindel, varscan2
- RIF1 | c.3961A>G p.I1321V | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF103 | c.66dup p.E23* | Frame Shift Ins (INS) | VAF 113/526 reads (21%) | called by mutect2, pindel, varscan2
- RNF126 | c.848del p.P283Lfs*6 | Frame Shift Del (DEL) | VAF 25/143 reads (17%) | called by mutect2, varscan2
- RNF213 | c.3094G>A p.V1032M | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RPE65 | c.596dup p.N199Kfs*35 | Frame Shift Ins (INS) | VAF 57/272 reads (21%) | called by mutect2, pindel, varscan2
- RPL13A | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2
- RPRD2 | c.3298G>A p.G1100R | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RRBP1 | c.944C>G p.A315G | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); called by muse, varscan2
- SAP130 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SBF1 | c.5425T>C p.F1809L | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SCD5 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCLY | c.343A>T p.I115F (on ENST00000651534; = p.I107F on NM_016510.7) | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SCN7A | c.2696dup p.N899Kfs*39 | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | called by mutect2, pindel
- SCN8A | c.5272G>A p.V1758M | Missense Mutation (SNP) | VAF 90/392 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCRT1 | c.952T>C p.Y318H | Missense Mutation (SNP) | VAF 97/328 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SEC14L5 | c.1192del p.V398* | Frame Shift Del (DEL) | VAF 81/331 reads (24%) | called by mutect2, pindel, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, varscan2
- SETD1B | c.3406del p.D1136Tfs*8 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- SF3B2 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SF3B4 | c.1060del p.R354Efs*26 | Frame Shift Del (DEL) | VAF 11/137 reads (8%) | called by pindel, varscan2*
- SFSWAP | c.1009A>G p.S337G | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SH3PXD2B | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- SIN3A | c.2280G>A p.R760= | Splice Region (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- SIX5 | c.49del p.E17Rfs*91 | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | called by mutect2, pindel, varscan2
- SLC13A3 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SLC22A23 | c.1981T>C p.Y661H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC6A1 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A19 | c.1441T>C p.W481R | Missense Mutation (SNP) | VAF 158/622 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLFN14 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SMAP1 | c.413A>T p.N138I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMARCA1 | c.1572G>A p.W524* | Nonsense Mutation (SNP) | VAF 47/223 reads (21%) | called by muse, mutect2, varscan2
- SMARCA4 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 84/563 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SMARCC2 | c.791del p.N264Tfs*14 | Frame Shift Del (DEL) | VAF 101/350 reads (29%) | called by mutect2, varscan2
- SMARCC2 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SNAPC4 | c.3127T>A p.F1043I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SOBP | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 89/384 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOCS5 | c.640dup p.M214Nfs*3 | Frame Shift Ins (INS) | VAF 28/138 reads (20%) | called by mutect2, pindel, varscan2
- SOX17 | c.746dup p.T250Hfs*115 | Frame Shift Ins (INS) | VAF 41/232 reads (18%) | called by mutect2, pindel, varscan2
- SPATA4 | c.366del p.K122Nfs*8 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- SPATA7 | c.1277del p.N426Tfs*3 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- SPC24 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- SPP1 | c.712C>A p.H238N (on ENST00000395080 / NM_001040058.2; = p.H224N on NM_000582.2) | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SPTAN1 | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 122/434 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- STARD9 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2
- STIM2 | c.1606C>A p.P536T | Missense Mutation (SNP) | VAF 132/447 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STPG2 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2
- STXBP5 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SUZ12 | c.2134T>C p.F712L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SV2C | c.1637-1G>T p.X546_splice | Splice Site (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2
- SYT5 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TACC2 | c.5186C>A p.T1729N | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- TAL1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TANC1 | c.4724C>T p.A1575V | Missense Mutation (SNP) | VAF 95/361 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TBL1XR1 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TBX1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TBXT | c.1003A>C p.S335R | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2
- TERB2 | c.285dup p.E96Rfs*8 | Frame Shift Ins (INS) | VAF 25/111 reads (23%) | called by mutect2, pindel, varscan2
- TFRC | c.965C>A p.P322Q | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM108 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- TMEM250 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 43/170 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TMEM52B | c.284G>A p.S95N (on ENST00000381923 / NM_001079815.1; = p.S75N on NM_153022.4) | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM92 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TNP2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNXB | c.7987del p.E2663Sfs*2 (on ENST00000647633; = p.E2416Sfs*2 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/203 reads (30%) | called by mutect2, varscan2
- TOGARAM1 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- TOMM40 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TP73 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TRAF6 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, varscan2
- TRIML2 | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TRIO | c.3125G>A p.G1042D | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIOBP | c.4277T>C p.V1426A | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP10 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | called by muse, mutect2, varscan2
- TRRAP | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TTI1 | c.2009T>C p.V670A | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- TTI1 | c.1865G>C p.S622T | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.678); called by muse, varscan2
- TTN | c.58937G>T p.W19646L (on ENST00000591111; = p.W12222L on NM_003319.4) | Missense Mutation (SNP) | VAF 80/473 reads (17%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UCP3 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.7558C>T p.H2520Y | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS35 | c.2106del p.A703Lfs*2 | Frame Shift Del (DEL) | VAF 81/359 reads (23%) | called by mutect2, pindel, varscan2
- WBP1L | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WNK1 | c.2462G>A p.G821D | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- WSB1 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWC2 | c.2767A>G p.T923A | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XRCC6 | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); called by muse, mutect2
- YARS1 | c.752A>C p.E251A | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YLPM1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2
- YWHAQ | c.552C>G p.N184K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, varscan2
- ZBTB12 | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- ZBTB7C | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ZC3H18 | c.1668-2A>G p.X556_splice | Splice Site (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- ZFHX3 | c.2287del p.E763Sfs*61 | Frame Shift Del (DEL) | VAF 77/319 reads (24%) | called by pindel, varscan2
- ZFP1 | c.936_938del p.I313del | In Frame Del (DEL) | VAF 23/122 reads (19%) | called by mutect2, pindel, varscan2
- ZKSCAN7 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZMYM2 | c.3749del p.N1250Ifs*3 | Frame Shift Del (DEL) | VAF 56/182 reads (31%) | called by mutect2, varscan2
- ZNF215 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF300 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF320 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF445 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ZNF462 | c.5195C>T p.A1732V | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZNF469 | c.4054dup p.H1352Pfs*3 (on ENST00000437464; = p.H1380Pfs*3 on NM_001367624.2) | Frame Shift Ins (INS) | VAF 133/661 reads (20%) | called by mutect2, pindel, varscan2
- ZNF469 | c.10896del p.R3634Efs*58 (on ENST00000437464; = p.R3662Efs*58 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 56/265 reads (21%) | called by mutect2, pindel, varscan2
- ZNF638 | c.4439A>G p.K1480R | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.091); called by muse, mutect2
- ZNF696 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ZNF705D | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ZNF804B | c.3946C>A p.P1316T | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM5 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 43/483 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZUP1 | c.922T>A p.L308I | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCA13 | c.5706G>A p.E1902= | Silent (SNP) | VAF 77/340 reads (23%) | called by muse, mutect2, varscan2
- ABCB5 | c.3336C>A p.A1112= (on ENST00000404938 / NM_001163941.2; = p.A667= on NM_178559.6) | Silent (SNP) | VAF 77/443 reads (17%) | called by muse, mutect2, varscan2
- ABCC5 | c.2088C>T p.A696= | Silent (SNP) | VAF 11/372 reads (3%) | called by muse, mutect2
- AC138647.1 | c.132G>A p.A44= | Silent (SNP) | VAF 57/201 reads (28%) | called by muse, mutect2, varscan2
- ACHE | c.780C>T p.S260= | Silent (SNP) | VAF 64/288 reads (22%) | catalogued as rs757718824; called by muse, mutect2, varscan2
- ACTN3 | c.1563T>A p.I521= | Silent (SNP) | VAF 62/261 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.1959C>T p.P653= | Silent (SNP) | VAF 69/368 reads (19%) | called by muse, mutect2, varscan2
- ADCK1 | c.1344C>T p.R448= | Silent (SNP) | VAF 33/252 reads (13%) | catalogued as rs774900095; called by muse, mutect2, varscan2
- ADRB2 | c.634C>T p.L212= | Silent (SNP) | VAF 87/351 reads (25%) | called by muse, mutect2, varscan2
- AKAIN1 | c.174C>T p.G58= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs895646791; called by muse, mutect2, varscan2
- AKAP8L | c.1728A>T p.A576= | Silent (SNP) | VAF 74/389 reads (19%) | called by muse, mutect2, varscan2
- ANKDD1A | c.390C>T p.C130= | Silent (SNP) | VAF 69/294 reads (23%) | catalogued as rs372737984; called by muse, mutect2, varscan2
- ARHGAP20 | c.3447C>T p.S1149= | Silent (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.2733G>A p.Q911= | Silent (SNP) | VAF 103/310 reads (33%) | called by muse, mutect2, varscan2
- ASPDH | c.30C>T p.G10= | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as rs147876313; called by muse, mutect2, varscan2
- BBS2 | c.1944T>C p.Y648= | Silent (SNP) | VAF 68/357 reads (19%) | catalogued as rs1014315603; called by muse, mutect2, varscan2
- BIRC6 | c.222C>T p.S74= | Silent (SNP) | VAF 115/590 reads (19%) | called by muse, mutect2, varscan2
- C2orf78 | c.2376C>T p.T792= | Silent (SNP) | VAF 51/180 reads (28%) | called by muse, mutect2, varscan2
- C4BPA | c.816T>A p.V272= | Silent (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- C5orf52 | c.93C>G p.A31= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- C8orf34 | c.282G>T p.R94= | Silent (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
- CAPN15 | c.1950G>A p.T650= | Silent (SNP) | VAF 98/537 reads (18%) | catalogued as rs754630964, COSV99562469; called by muse, mutect2, varscan2
- CBLN1 | c.516G>A p.E172= | Silent (SNP) | VAF 94/300 reads (31%) | catalogued as COSV54654552; called by muse, mutect2, varscan2
- CDHR2 | c.2010C>T p.C670= | Silent (SNP) | VAF 30/410 reads (7%) | catalogued as rs139851773; called by muse, mutect2
- CEP170 | c.858C>T p.D286= | Silent (SNP) | VAF 61/251 reads (24%) | called by muse, mutect2, varscan2
- CHD6 | c.1053T>C p.F351= | Silent (SNP) | VAF 86/323 reads (27%) | called by muse, mutect2, varscan2
- CHST6 | c.495C>T p.C165= | Silent (SNP) | VAF 110/651 reads (17%) | catalogued as rs1374364102, CM053810, CX054510; called by muse, mutect2
- CILP2 | c.3327C>A p.A1109= | Silent (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- COL4A6 | c.246A>G p.P82= | Silent (SNP) | VAF 69/262 reads (26%) | catalogued as rs1389222681; called by muse, mutect2, varscan2
- COL6A6 | c.2806T>C p.L936= | Silent (SNP) | VAF 9/191 reads (5%) | called by muse, mutect2
- CRIPT | c.198C>T p.H66= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- CRTC3 | c.1182G>A p.T394= | Silent (SNP) | VAF 114/472 reads (24%) | catalogued as rs199722697, COSV99185650; called by muse, mutect2, varscan2
- CSAG1 | c.21C>T p.C7= | Silent (SNP) | VAF 17/443 reads (4%) | called by muse, mutect2
- CXCR3 | c.780C>T p.V260= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as rs753816320; called by muse, mutect2, varscan2
- DOCK4 | c.721C>T p.L241= | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as rs759745721; called by muse, mutect2, varscan2
- DPH2 | c.159G>A p.Q53= | Silent (SNP) | VAF 63/239 reads (26%) | called by muse, mutect2, varscan2
- EBF3 | c.360C>A p.V120= | Silent (SNP) | VAF 93/205 reads (45%) | called by muse, mutect2, varscan2
- EGFLAM | c.1419G>T p.T473= | Silent (SNP) | VAF 88/316 reads (28%) | called by muse, mutect2, varscan2
- EIF3B | c.966C>T p.D322= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as rs945733263, COSV62803918; called by muse, mutect2, varscan2
- EPHA8 | c.912C>T p.A304= | Silent (SNP) | VAF 67/258 reads (26%) | called by muse, mutect2, varscan2
- ESPL1 | c.4267C>A p.R1423= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as COSV99228986; called by muse, mutect2, varscan2
- ETV1 | c.201T>C p.D67= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV54137938; called by muse, mutect2, varscan2
- F2 | c.633G>A p.E211= | Silent (SNP) | VAF 73/311 reads (23%) | called by muse, mutect2, varscan2
- FAM110B | c.996C>T p.D332= | Silent (SNP) | VAF 63/305 reads (21%) | called by muse, mutect2, varscan2
- FAM177B | c.216A>T p.G72= | Silent (SNP) | VAF 34/379 reads (9%) | called by muse, mutect2
- FAM222A | c.891C>G p.P297= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- FANCA | c.4320G>A p.Q1440= | Silent (SNP) | VAF 197/658 reads (30%) | called by muse, mutect2, varscan2
- FAT3 | c.1089C>T p.Y363= | Silent (SNP) | VAF 76/213 reads (36%) | catalogued as rs1023038105; called by muse, mutect2, varscan2
- FCGBP | c.6810C>A p.S2270= | Silent (SNP) | VAF 211/1586 reads (13%) | called by mutect2, varscan2
- FIZ1 | c.693G>A p.P231= | Silent (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- FLII | c.627G>A p.Q209= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs759987113; called by muse, mutect2, varscan2
- FN1 | c.6300A>G p.P2100= (on ENST00000359671 / NM_001365524.2; = p.P2010= on NM_212476.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as rs768339722; called by muse, mutect2, varscan2
- FSIP2 | c.3369C>T p.S1123= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as rs951936498; called by muse, mutect2, varscan2
- GABBR2 | c.1008G>A p.Q336= | Silent (SNP) | VAF 61/291 reads (21%) | called by muse, mutect2, varscan2
- GHSR | c.999A>G p.A333= | Silent (SNP) | VAF 36/228 reads (16%) | catalogued as rs1436990929; called by muse, mutect2, varscan2
- GPN1 | c.1062G>A p.E354= | Silent (SNP) | VAF 40/223 reads (18%) | called by muse, mutect2, varscan2
- GPR20 | c.552G>A p.S184= | Silent (SNP) | VAF 51/302 reads (17%) | catalogued as rs368723756; called by muse, mutect2, varscan2
- GRM1 | c.3165C>T p.P1055= | Silent (SNP) | VAF 52/244 reads (21%) | catalogued as rs1178140918, COSV51198312; called by muse, mutect2
265 further variants in this file (0 protein-altering or splice-affecting, 139 silent, 126 other) are not listed here.
